Gene-level copy-number profile of tumor specimen SM-JU33R from CPTAC case C317832, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU33R: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b69541a3-9321-4845-aa3c-8e5ef647bbb2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105209 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/08afaaa3-dab5-4bea-bb68-fa8acf2a3f24

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 135; copy number 1: 7,934; copy number 2: 42,683; copy number 3: 8,098; copy number 5: 3; copy number 9: 13; copy number 19: 18; copy number 24: 4; copy number 29: 1; copy number 45: 11; copy number 63: 1; copy number 84: 3; copy number 112: 3; copy number 114: 2.

Homozygous deletions (total copy number 0; autosomes only): 135 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,460,926–30,575,012, 132 genes (broad region; genes not listed).
- chr22:18,623,339–18,653,617, 3 genes: SUSD2P2, CA15P2, PPP1R26P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 59 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,576,052–55,572,988, 14 genes, copy number 24–114: AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.
- chr7:55,656,768–55,741,869, 7 genes, copy number 45: AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3.
- chr7:56,051,685–56,063,989, 1 gene, copy number 45 (within-gene range 2–45): CCT6A.
- chr7:56,060,470–56,092,996, 3 genes, copy number 45: SNORA15, SUMF2, PHKG1.
- chr9:38,571,358–39,508,885, 18 genes, copy number 19 (within-gene range 2–19): ANKRD18A, FAM201A, YWHABP1, RNU6-765P, AL845311.1, VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3.
- chr9:39,748,514–39,810,097, 2 genes, copy number 5: GLIDR, BX664615.1.
- chr9:39,816,599–39,874,562, 1 gene, copy number 5 (within-gene range 2–5): BX664615.2.
- chr9:62,606,797–62,864,957, 13 genes, copy number 9: RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, MYO5BP2, ADGRF5P1.

Autosomal genes at a single copy (total copy number 1): 5,078. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
